Gene-level copy-number profile of tumor specimen TCGA-DK-A2I4-01A from TCGA case TCGA-DK-A2I4, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DK-A2I4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.34e2ff35-b26a-4040-9fa3-acff7f59951d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A2I4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/173120e7-7e2f-4ad1-9321-5098ab38dce8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 946; copy number 2: 20,713; copy number 3: 17,444; copy number 4: 12,767; copy number 5: 6,320; copy number 6: 482; copy number 7: 1,033; copy number 8: 26; copy number 9: 8; copy number 11: 5; copy number 14: 1; copy number 18: 36; copy number 23: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A2I4-01A-11D-A219-01): tumor purity 0.29, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,232,612–48,599,436, 11 genes (within-gene range 0–3): ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,900 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,040,140–180,890,279, 2,591 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr3:11,556,069–13,638,422, 41 genes, copy number 11–18 (within-gene range 3–18): VGLL4, AC022001.2, AC022001.3, TAMM41, FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1, RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022, IQSEC1, AC069271.1, NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2.
- chr3:15,601,341–16,697,479, 26 genes, copy number 8 (within-gene range 3–8): BTD, ANKRD28, MIR3134, AC090950.2, AC090950.1, RN7SL4P, AC090945.1, MIR563, IMPDH1P8, AC090946.1, GALNT15, AC090953.2, DPH3, OXNAD1, AC090953.1, RFTN1, AC090948.1, AC090948.2, AC090948.3, AC090948.4, AC010727.1, LINC00690, AC010139.1, DAZL, AC091493.1, CDYLP1.
- chr3:86,481,943–88,601,402, 24 genes, copy number 14–23: LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5.
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr6:4,979,072–25,781,199, 321 genes, copy number 7 (broad region; genes not listed).
- chr6:37,433,219–37,699,306, 8 genes, copy number 9 (within-gene range 4–9): CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1.
- chr8:49,330,210–145,066,685, 1,470 genes, copy number 5–6 (broad region; genes not listed).
- chr9:14,475–10,612,723, 149 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:40,692,439–41,574,745, 5 genes, copy number 5 (within-gene range 2–5): CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1.
- chr12:67,989,445–68,234,686, 1 gene, copy number 6 (within-gene range 4–6): IFNG-AS1.
- chr12:68,035,767–70,243,379, 55 genes, copy number 6 (within-gene range 2–6): HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1.
- chr15:74,899,992–101,933,350, 711 genes, copy number 5–7 (broad region; genes not listed).
- chr17:36,601,583–40,017,813, 125 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:28,563,850–64,313,132, 918 genes, copy number 5 (broad region; genes not listed).
- chr21:10,328,411–46,665,124, 745 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 946. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
